Surgical pathology report (de-identified scan), TCGA case TCGA-NK-A5CX, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - Rush University, specimen TCGA-NK-A5CX-01A (Primary Tumor).

[page 1 of 3]
PATHOLOGY SURGICAL

Results

Status: Final result

Entry Date

Component Results

PATHOLOGY RESULT:

Department of Pathology

Final

Clinical Data Repository* This report may not match the original report format

FINAL DIAGNOSIS

- A. (Level 11 lymph node; excision): Fragments of lymphoid tissue negative for malignancy.
- B. (Lung, right lower lobe; lobectomy): Moderately-differentiated squamous cell carcinoma, grade 2, with associated necrosis, measuring 4.5 cm in greatest dimensions. Five peri-bronchial lymph nodes negative for metastatic tumor. The bronchial, vascular and visceral pleural margins are free of malignancy. Remaining lung with no significant pathologic changes. Stage pT2bN0(PLO). See note.
- C. (Level 7 lymph node; excision): Fragments of lymphoid tissue negative for malignancy.

INTRAOPERATIVE CONSULTATION

- B. RIGHT LOWER LOBE, FROZEN ON BRONCHIAL MARGIN: (B91) Negative for malignancy.

NOTE

ICD-O-3

Carcinoma, squamous cell N65
8070/3

Site R Lung, lower lobe C34.3

J.S 1/14/13

[page 2 of 3]
B. Lung Cancer Summary

Specimen type: Right lower lobectomy

Tumor location: Right lower lobe

Tumor size: 4.5 x 2.8 x 2.7 cm

Histologic type: Squamous

Histologic grade: 2

Status of margins:

Bronchial: Free of tumor

Vascular: Free of tumor

Parenchymal: Free of tumor

Pleural: Visceral pleura free of tumor

Visceral/Parietal pleural invasion: Absent

Lymphatic vascular invasion: Absent

Lymph node status: Negative (levels 7, 11 and peri-bronchial)

Extension into other structures: Absent

Non-neoplastic pathology: None

TMN stage: pT2bN0(PLO)

GROSS DESCRIPTION

A. The specimen is labeled level 11 lymph node. Received fresh is a 1 x 0.6 x 0.4 cm aggregate of lymphoid tissue that is entirely submitted in cassette A1.

B. The specimen is labeled right lower lobe. Received fresh for frozen section is a right lower lobectomy specimen. The specimen measures 14.1 x 10.2 x 6.4 cm. There is a 4.5 x 2.8 x 2.7 cm ill defined mass that is located 2.7 cm from the bronchial margin. The mass has a white-tan, green cut surface with focal areas of necrosis. The remaining lung is composed of spongy pink tissue. Sections are submitted as follows: bronchial margin is submitted for frozen section; the remnant placed in cassette B91. Additional sections are submitted as follows: B1, hilar lymph nodes; B2, vascular margin; B3, additional lymph nodes; B4 and B5, tumor with overlying pleura; B6, tumor with adjacent normal tissue; B7, normal lung.

C. The specimen is labeled level 7 lymph node. Received fresh is a 6.1 x 4.8 x 2.8 cm fragment of lymphoid tissue. Representative sections are submitted in cassettes C1 through C4.

SPECIMEN(S) RECEIVED

A: LEVEL 11 LYMPH NODE

B: RIGHT LOWER LOBE, FROZEN ON BRONCHIAL MARGIN

C: LEVEL 7 LYMPH NODE

* The above listed tests (if any) were developed and the performance characteristics determined by Department of Pathology. These tests have not been cleared or approved for commercial use by the U.S. Food and Drug Administration. The FDA has determined that FDA review is not required for such in-house assays. (21 CFR 809.30(e))

OPERATIVE INFORMATION

DIAGNOSIS: LUNG CANCER; PROCEDURE: BRONCHOSCOPY FLEXIBLE FIBEROPTIC, THORACOSCOPY VIDEO ASSISTED

[page 3 of 3]
INTRADEPARTMENT CONSULTATION PATHOLOGIST: QA COMMITTEE

ICD-9(s): 162.5

CPT(s): A: 88305

B: 88307, 88331

C: 88305

The attending pathologist was physically present when this specimen was diagnosed, and actively participated in all key decisions.

Lab and Collection

PATHOLOGY SURGICAL

Pathology

Procedure Location:

Case is "circle"		✓

Source: NCI Genomic Data Commons file cf342d16-8509-4ea6-b5be-cc1899538d98 (TCGA-NK-A5CX.ED75BACE-AC37-41FE-ACE7-8E1403C97094.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).